Somatic mutation profile of tumor specimen TCGA-S9-A7J1-01A (aliquot TCGA-S9-A7J1-01A-21D-A34J-08) from TCGA case TCGA-S9-A7J1, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 43.6 years (15,926 days).
Specimen TCGA-S9-A7J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07d9a4b2-fe0f-4994-9b2c-45e126c51a36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7J1-10A (Blood Derived Normal), aliquot TCGA-S9-A7J1-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c4dfc18-5d1c-4258-9e3d-687f5bfdc0ac

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Frame Shift Del 3, Silent 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 41/105 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1359_1361del p.E453del | In Frame Del (DEL) | VAF 18/145 reads (12%) | hotspot (GDC flag); catalogued as rs587776933; called by pindel, varscan2
- APAF1 | c.1111A>T p.S371C (on ENST00000551964 / NM_181861.2; = p.S360C on NM_001160.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264896516, COSV100244389; called by muse, mutect2, varscan2
- CHRFAM7A | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100241689; called by mutect2, varscan2
- COPB1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV99999868; called by muse, mutect2, varscan2
- ECRG4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376920426, COSV53001310; called by muse, mutect2, varscan2
- EFNA3 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100860872; called by muse, mutect2, varscan2
- FES | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100183309; called by muse, mutect2, varscan2
- IQGAP2 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99167919; called by muse, mutect2
- KIF23 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs377663038; called by muse, mutect2, varscan2
- NPBWR2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs781390433, COSV63899738; called by muse, mutect2
- PODXL | c.1141T>A p.C381S (on ENST00000378555 / NM_001018111.3; = p.C349S on NM_005397.4) | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100539747, COSV59868583; called by muse, mutect2, varscan2
- RIBC2 | c.933C>G p.D311E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.46); catalogued as COSV100734217; called by muse, mutect2, varscan2
- TOP3A | c.2700C>A p.S900R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100329285; called by muse, mutect2, varscan2
- CIC | c.4034_4035del p.V1345Gfs*16 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | called by pindel, varscan2
- FUBP1 | c.1328_1329del p.I443Rfs*47 | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | called by mutect2, pindel, varscan2
- GREB1 | c.5584_5585del p.L1862Kfs*18 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- MUC2 | c.771G>T p.P257= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- SLITRK5 | c.336A>T p.L112= | Silent (SNP) | VAF 78/216 reads (36%) | catalogued as COSV100281136; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1621_*1623del | 3'UTR (DEL) | VAF 66/249 reads (27%) | called by mutect2, pindel, varscan2
